TCGA case TCGA-44-3918 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e3b6b72-142d-4b8d-a462-28a205796e41

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.9 years (22,236 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 543 days (1.5 years); Days to treatment end: 648 days (1.8 years); Number of cycles: 6; Treatment dose: 3,380 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Initial disease status: Recurrent Disease; Days to treatment start: 543 days (1.5 years); Days to treatment end: 648 days (1.8 years); Number of cycles: 6; Treatment dose: 5,660 mg; Prescribed dose: 930; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 686 days (1.9 years); Days to treatment end: 697 days (1.9 years); Treatment dose: 3,000 cGy; Course number: 1; Number of fractions: 10; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 62.3 years (22,747 days); Days to diagnosis: 511 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.3 years (22,747 days); Days to diagnosis: 511 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (6 entries)
- Days to follow up: 197 days; Disease response: Tumor Free.
- Day 511 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 511 days (1.4 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 715 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 1,036 days (2.8 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Other.
- ECOG performance status: 0; Timepoint: Other.

Other clinical attributes
- DLCO (% of predicted): 76; FEV1/FVC before bronchodilator (%): 103; FEV1 before bronchodilator (% of reference): 104.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 1994.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-3918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 280 mg; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-44-3918-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 20.
  Slide TCGA-44-3918-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 20.
- Sample TCGA-44-3918-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-44-3918-01B-02-BS2: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 9; Percent stromal cells: 21; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
  Slide TCGA-44-3918-01B-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 22; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
- Sample TCGA-44-3918-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-3918-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-3918-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 600 mg; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Alimta.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 3, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 3, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,036 days; disease-specific survival: no event (censored), 1,036 days; disease-free interval: event (new tumor event after initially disease-free), 511 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 511 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-3918-01A-01D-A273-01): tumor purity 0.45, ploidy 1.8, whole-genome doublings 0.
